MMRF case MMRF_1949 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b032d68e-999f-4788-b486-6058541cfce4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.4 years (23,162 days); ISS stage: II; Days to last known disease status: 1,051 days (2.9 years); Days to last follow up: 1,051 days (2.9 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 667 days (1.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 400 days (1.1 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 184 days; Days to treatment end: 184 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 184 days; Days to treatment end: 184 days.
   Treatment given: Therapeutic agents: Elotuzumab + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 708 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.28 mg/dL; Immunoglobulin G 35.8 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 4.22 µg/mL; Lactate Dehydrogenase 8.15 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 9.4 g/dL; Glucose 5.61 mmol/L.
- Day 84 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 6.16 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.49 µg/mL; Lactate Dehydrogenase 7.2 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 8.2 mmol/L.
- Day 253 (ECOG 1): Hemoglobin 8.06 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 8.2 g/dL; Glucose 5.17 mmol/L.
- Day 323 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.7 g/L; Beta 2 Microglobulin 2.65 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 66 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 6.55 mmol/L.
- Day 428 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Immunoglobulin G 7.07 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 3.07 µg/mL; Lactate Dehydrogenase 8.32 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 526 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.01 mg/dL; Immunoglobulin G 7.61 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 4.09 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 7.37 mmol/L.
- Day 624 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.71 mg/dL; Immunoglobulin G 9.81 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 4.19 µg/mL; Lactate Dehydrogenase 8.02 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 6.99 mmol/L.
- Day 707 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.28 mg/dL; Immunoglobulin G 8.73 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 6.52 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 9.9 mmol/L.
- Day 792 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.94 mg/dL; Immunoglobulin G 7.25 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 4.36 µg/mL; Lactate Dehydrogenase 7.67 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 5.8 g/dL; Glucose 12.9 mmol/L.
- Day 876 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.04 mg/dL; Immunoglobulin G 8.04 g/L; Immunoglobulin A 2.81 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 4.13 µg/mL; Lactate Dehydrogenase 7.7 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 13.2 mmol/L.
- Day 960 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 5.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.73 mg/dL; Immunoglobulin G 6.45 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 3.73 µg/mL; Lactate Dehydrogenase 6.32 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 8.09 mmol/L.
- Day 1,051 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.94 mg/dL; Immunoglobulin G 0.209 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.209 g/L; Beta 2 Microglobulin 3.54 µg/mL; Lactate Dehydrogenase 6.12 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 8.86 mmol/L.

Other clinical attributes
- Day -5: Weight: 78 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1949_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1949_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
